Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A42F, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A42F-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: URINARY BLADDER AND PROSTATE, RADICAL CYSTOPROSTATECTOMY -

- A. INVASIVE HIGH GRADE UROTHELIAL CARCINOMA WITH SQUAMOUS CELL FEATURES INVOLVING RIGHT POSTERIOR BLADDER WALL (See comment).
- B. BLADDER TUMOR MEASURES 0.8 x 0.4 CM.
- C. TUMOR INVADES DETRUSOR MUSCLE (MUSCULARIS PROPRIA) AND EXTENDS INTO PROSTATIC STROMA
- D. SURGICAL MARGINS ARE FREE OF TUMOR.
- E. TNM PATHOLOGIC STAGE: pT4a N1 Mx (see parts 3-5, and synoptic).
- F. BACKGROUND UROTHELIUM WITH DENSE NODULAR LYMPHOCYTIC INFILTRATION AND REACTIVE CHANGES.
- G. FOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (HG-PIN).
- H. BACKGROUND PROSTATE WITH PATCHY CHRONIC AND ACUTE INFLAMMATION AND REACTIVE CHANGES.

PART 2: DISTAL URETHRAL MARGIN, BIOPSY -

- A. BENIGN FIBROMUSCULAR TISSUE.
- B. NO UROTHELIUM OR NEOPLASIA IS PRESENT.

PART 3: LEFT PELVIC LYMPH NODES, LYMPHADENECTOMY - NO EVIDENCE OF NEOPLASIA IN FIVE LYMPH NODES (0/5).

PART 4: RIGHT PELVIC LYMPH NODE, BIOPSY - METASTATIC UROTHELIAL CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).

PART 5: RIGHT PELVIC LYMPH NODES #2, LYMPHADENECTOMY - NO EVIDENCE OF NEOPLASIA IN FIVE LYMPH NODES (0/5).

PART 6: LEFT URETER, EXCISION - SEGMENT OF BENIGN URETER WITH CHRONIC AND ACUTE INFLAMMATION.

PART 7: RIGHT URETER, EXCISION - SEGMENT OF BENIGN URETER WITH CHRONIC AND FOCAL ACUTE INFLAMMATION.

COMMENT:

Immunohistochemistry shows tumor cells positive for thrombomodulin and p63, and negative for CK20, CK7, CK5/6, prostate specific antigen (PSA) and androgen receptor (AR) immunohistochemical stains. This is consistent with above diagnosis.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE:

Radical cystoprostatectomy

TUMOR SITE:

Posterior wall

TUMOR SIZE:

Greatest dimension: 0.8 cm

Additional dimensions: 0.4 cm

HISTOLOGIC TYPE:

Urothelial (transitional cell) carcinoma with squamous differentiation

ASSOCIATED EPITHELIAL LESIONS:

None identified

HISTOLOGIC GRADE:

Urothelial carcinoma - High-grade

TUMOR CONFIGURATION:

Ulcerated

PATHOLOGIC STAGING (pTNM):

pT4a

pN1

Number of nodes examined: 11

Number of nodes involved: 1

pMx

MARGINS:

Margins uninvolved by invasive carcinoma

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

Indeterminate

DIRECT EXTENSION OF INVASIVE TUMOR:

Prostatic stroma

ADDITIONAL PATHOLOGIC FINDINGS:

Inflammation/regenerative changes

Other: Biopsy site changes

100-0-3

Carcinoma, urothelial, NOS

8120/3

site: bladder, wall, posterior

C67.4

9-1-12

Source: NCI Genomic Data Commons file 39b73ad3-b26a-4c4f-b8b8-6ea666b7e631 (TCGA-BT-A42F.2A58F62D-F2F7-454A-A9E3-F7AE46DF70C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).